Somatic mutation profile of tumor specimen TCGA-AS-3777-01A (aliquot TCGA-AS-3777-01A-01D-0966-08) from TCGA case TCGA-AS-3777, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.1 years (23,039 days).
Specimen TCGA-AS-3777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccb99c99-911d-4e7b-82bc-1719307f9242.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AS-3777-10A (Blood Derived Normal), aliquot TCGA-AS-3777-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a7e2d7-5ee9-4e28-9145-a7499eed9512

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.10446C>G p.F3482L | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV57216869; called by muse, mutect2, varscan2
- ATP9A | c.2609C>G p.P870R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV58767874; called by muse, mutect2
- CFAP47 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1323139606, COSV52886160; called by muse, mutect2, varscan2
- DEPDC7 | c.748G>T p.D250Y (on ENST00000241051 / NM_001077242.2; = p.D241Y on NM_139160.2) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53807331; called by muse, mutect2, varscan2
- DSCAML1 | c.1228C>T p.R410C (on ENST00000321322; = p.R350C on NM_020693.4) | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260152977, COSV58393365; called by muse, mutect2, varscan2
- ITGA5 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.725); catalogued as COSV53218494; called by muse, mutect2, varscan2
- KRT85 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1187176684, COSV57737130; called by muse, mutect2, varscan2
- MAX | c.172-2A>G p.X58_splice | Splice Site (SNP) | VAF 22/127 reads (17%) | catalogued as COSV52417588, COSV52418923; called by muse, mutect2, varscan2
- MYH2 | c.2605C>T p.L869F | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV55440545; called by muse, mutect2
- MYO16 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201650171, COSV51782521; called by muse, mutect2, varscan2
- QPCT | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58120125; called by muse, mutect2, varscan2
- SLC12A2 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52472490; called by muse, mutect2, varscan2
- TFRC | c.2277G>T p.E759D | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV64055116; called by muse, mutect2, varscan2
- TRIM37 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51885051; called by muse, mutect2
- SCN1A | c.1336_1338del p.Q446del | In Frame Del (DEL) | VAF 41/82 reads (50%) | called by pindel, varscan2
- FREM2 | c.4330C>T p.L1444= | Silent (SNP) | VAF 24/227 reads (11%) | catalogued as COSV54841052; called by muse, mutect2
- NID1 | c.453C>T p.S151= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs201727792, COSV51622081; called by muse, mutect2, varscan2
- NUP210L | c.2085G>A p.A695= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs1050732640, COSV55149941, COSV99667285; called by muse, mutect2, varscan2
- RAB43 | c.96G>T p.T32= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59349244; called by mutect2, varscan2
- TSBP1 | c.1446A>G p.Q482= (on ENST00000617061; = p.Q487= on NM_006781.5) | Silent (SNP) | VAF 124/400 reads (31%) | catalogued as COSV66659535; called by muse, varscan2
